Somatic mutation profile of tumor specimen MBCproject_0280_T2_WES (aliquot MBCproject_0280_T2_WES_1) from CMI case MBCproject_0280, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.4 years (19,141 days).
Specimen MBCproject_0280_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f46b2912-425d-43ee-b306-da8b77d9a900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0280_SALIVA (Saliva), aliquot MBCproject_0280_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2549dd9-968e-4961-974f-f6eafba3cfc8

The open-access MAF lists 195 somatic variants for this specimen: 114 protein-altering or splice-affecting, 49 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 49, Nonsense Mutation 14, Intron 10, RNA 6, 3'Flank 5, 5'UTR 5, 3'UTR 3, 5'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2ML1 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 48/611 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV55291817; called by muse, mutect2
- AC011005.1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 62/548 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs771131597; called by muse, mutect2, varscan2
- AC099489.1 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs943307394; called by muse, mutect2
- AMER1 | c.2472G>C p.E824D | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV57667649; called by muse, mutect2
- ARID1A | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 38/453 reads (8%) | catalogued as COSV100251003; called by muse, mutect2
- BRINP2 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 25/418 reads (6%) | catalogued as COSV64175671; called by muse, mutect2
- CCDC85A | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as rs374836548; called by muse, mutect2
- CDAN1 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 57/687 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1226616378; called by muse, mutect2
- CDH1 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55731369, COSV55732870, COSV55741714; called by muse, mutect2
- CELSR3 | c.6436G>A p.V2146I | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs199670636; called by mutect2, varscan2
- CR1 | c.4760C>G p.S1587C | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV100887439; called by muse, mutect2
- CUBN | c.10819C>T p.H3607Y | Missense Mutation (SNP) | VAF 54/556 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs1352831722; called by muse, mutect2
- DHX34 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 40/352 reads (11%) | catalogued as rs1369352022, COSV100169943; called by muse, mutect2, varscan2
- DIAPH3 | c.1843C>T p.P615S (on ENST00000400324 / NM_001042517.2; = p.P352S on NM_030932.3) | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV57365643; called by muse, mutect2
- EPAS1 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 33/391 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.352); catalogued as COSV55383969; called by muse, mutect2
- EPHA3 | c.2772G>A p.W924* | Nonsense Mutation (SNP) | VAF 18/244 reads (7%) | catalogued as COSV60696993, COSV60718530; called by muse, mutect2
- FAM117B | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57419142; called by muse, varscan2
- FRMD8 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 85/545 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as rs368973734; called by muse, mutect2, varscan2
- FYB2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58582850; called by muse, mutect2
- GJC3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 66/648 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as COSV100458546; called by muse, mutect2
- HSD17B2 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as rs1345428711; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 35/614 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1482563087; called by muse, mutect2
- IL17RC | c.2048C>T p.S683L (on ENST00000295981 / NM_153461.4; = p.S597L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55974721; called by muse, mutect2, varscan2
- JMJD6 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV57971821, COSV57972254, COSV57972715; called by muse, mutect2
- KIAA1109 | c.3661C>T p.Q1221* | Nonsense Mutation (SNP) | VAF 24/296 reads (8%) | catalogued as rs780100006; called by muse, mutect2
- KIAA1522 | c.2887C>T p.P963S (on ENST00000373480 / NM_001198972.2; = p.P1022S on NM_020888.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1430897038, COSV99615275; called by muse, mutect2, varscan2
- KLHL36 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.338); catalogued as rs770097199; called by muse, mutect2, varscan2
- LRFN5 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99983193; called by muse, mutect2, varscan2
- MAN1B1 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 21/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65378795; called by muse, mutect2
- MAP2 | c.4364G>A p.R1455K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as COSV52294456; called by muse, mutect2
- MBD1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 61/664 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs1057340110; called by muse, mutect2
- MRPL53 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs925154921, COSV50688696; called by muse, mutect2
- MYBPC2 | c.2397G>C p.K799N | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100732017; called by muse, mutect2
- MYH9 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 33/484 reads (7%) | catalogued as COSV99340092; called by muse, mutect2
- NCOR1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1325843352, COSV51966620; called by muse, mutect2
- NEB | c.18466G>C p.E6156Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1427816148, COSV51442210; called by muse, mutect2
- NEURL4 | c.2144C>G p.S715C | Missense Mutation (SNP) | VAF 37/776 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs1040359710; called by muse, mutect2
- OR7D2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV100712959, COSV60141078; called by muse, mutect2
- OSBPL3 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.62); catalogued as COSV57655601, COSV57663354; called by muse, mutect2
- P3H4 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as rs782262900, COSV58635499; called by muse, mutect2, varscan2
- PDAP1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as rs771952212; called by muse, mutect2, varscan2
- PLEC | c.9109G>A p.E3037K (on ENST00000322810 / NM_201380.4; = p.E2927K on NM_000445.5) | Missense Mutation (SNP) | VAF 41/549 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs782610157, COSV59693789; called by muse, mutect2
- PPID | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 36/544 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1254303632; called by muse, mutect2
- PRG4 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV63356171; called by muse, mutect2, varscan2
- PTPRR | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.749); catalogued as rs144147611; called by mutect2, varscan2
- RABIF | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs779708894; called by muse, mutect2
- RALGAPA2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 30/280 reads (11%) | catalogued as rs1404186195; called by muse, mutect2, varscan2
- RECQL4 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 57/536 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1420581482, COSV99468089; called by muse, mutect2, varscan2
- RETREG1 | c.1175C>T p.S392L (on ENST00000306320 / NM_001034850.2; = p.S251L on NM_019000.4) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV100104348; called by muse, mutect2
- RFX5 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 39/780 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.335); catalogued as rs999104857; called by muse, mutect2
- RYR1 | c.8702C>T p.T2901I | Missense Mutation (SNP) | VAF 56/462 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.306); catalogued as COSV100614498; called by muse, mutect2, varscan2
- RYR2 | c.14084C>T p.S4695L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV63691561; called by muse, mutect2
- SEL1L3 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs866916220; called by muse, mutect2
- SETDB1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54978232; called by muse, mutect2, varscan2
- SH3PXD2A | c.2863G>A p.G955R (on ENST00000369774 / NM_001365079.1; = p.G927R on NM_014631.2) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138239379; called by muse, mutect2, varscan2
- SHE | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 38/562 reads (7%) | catalogued as rs751737504, COSV59071139; called by muse, mutect2
- SLITRK1 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV65677893; called by muse, mutect2
- SPPL2B | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.135); catalogued as COSV71765503; called by muse, mutect2
- SPTA1 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 44/694 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as rs931833361, COSV63754419, COSV63755006; called by muse, mutect2
- ST6GAL2 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 10/139 reads (7%) | PolyPhen possibly damaging (0.769); catalogued as rs1345582889, COSV64528104; called by muse, mutect2
- TMC2 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775597370; called by muse, mutect2, varscan2
- TRIM50 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs782075450; called by muse, mutect2
- TUT1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 35/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765502633, COSV53469112, COSV99545558; called by muse, mutect2
- WIPF2 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 43/464 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs896400409; called by muse, mutect2
- ZNF488 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 65/575 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs536291384; called by muse, mutect2, varscan2
- AAK1 | c.2852C>G p.S951C | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA6 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- ABCG4 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ACACA | c.6076G>A p.E2026K | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY10 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 31/653 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2
- BACH1 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 17/352 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); called by muse, mutect2
- BCAR1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 62/476 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C21orf62 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CAMTA1 | c.4537C>T p.Q1513* | Nonsense Mutation (SNP) | VAF 38/382 reads (10%) | called by muse, mutect2, varscan2
- CBFB | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC7 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- CCNJ | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 30/285 reads (11%) | called by muse, mutect2, varscan2
- CDH2 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHAMP1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- CHKB | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST7 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CRY2 | c.1739T>C p.V580A | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); called by muse, mutect2
- DAOA | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2
- DBF4 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, varscan2
- DHX35 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2
- G6PD | c.642G>A p.L214= | Splice Region (SNP) | VAF 43/425 reads (10%) | called by muse, varscan2
- GAS2L2 | c.2551C>G p.P851A | Missense Mutation (SNP) | VAF 56/464 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, varscan2
- HEBP1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 52/582 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- IGLV5-45 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL10RA | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 52/577 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); called by muse, mutect2
- KIAA1109 | c.10286C>T p.S3429L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MVP | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MYO5A | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 46/414 reads (11%) | called by muse, mutect2, varscan2
- NOS1AP | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 37/557 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PDE4DIP | c.3454G>C p.E1152Q | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); called by muse, mutect2
- PIKFYVE | c.3954C>G p.I1318M | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.115); called by muse, mutect2
- PKD1L1 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); called by muse, mutect2
- PRICKLE1 | c.1245G>C p.M415I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2
- PROB1 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PTPN5 | c.483G>A p.L161= | Splice Region (SNP) | VAF 22/447 reads (5%) | called by muse, mutect2
- RPGRIP1L | c.3070G>C p.E1024Q | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.106); called by muse, mutect2
- SCPEP1 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.125); called by muse, mutect2
- SERPINA7 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- SERPINE1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2
- SH3KBP1 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SHANK1 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 25/542 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- SPAM1 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STAB2 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- SVEP1 | c.3217C>T p.P1073S | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.46996G>A p.E15666K (on ENST00000591111; = p.E8242K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | PolyPhen benign (0.269); called by muse, mutect2, varscan2
- UGT1A9 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ZC3H12D | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 61/544 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF792 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- ADGRA2 | c.3603C>G p.L1201= | Silent (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- ARHGAP19 | c.303C>T p.L101= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as rs1241793564, COSV57396682; called by muse, mutect2
- BORCS6 | c.162G>A p.A54= | Silent (SNP) | VAF 30/348 reads (9%) | catalogued as rs1360634411; called by muse, mutect2
- CARMIL3 | c.2250G>A p.Q750= | Silent (SNP) | VAF 31/446 reads (7%) | called by muse, mutect2
- CASP1 | c.774C>T p.L258= (on ENST00000436863 / NM_033292.4; = p.L237= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/377 reads (8%) | called by muse, mutect2
- CCDC3 | c.600C>T p.V200= | Silent (SNP) | VAF 38/576 reads (7%) | called by muse, mutect2
- CFAP58 | c.1644G>A p.Q548= | Silent (SNP) | VAF 34/248 reads (14%) | called by muse, mutect2, varscan2
- DLG5 | c.897C>T p.L299= | Silent (SNP) | VAF 27/274 reads (10%) | catalogued as rs1027473660; called by muse, mutect2
- DNAJB1 | c.21G>A p.Q7= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- DPP9 | c.1317C>A p.L439= (on ENST00000598800; = p.L468= on NM_139159.5) | Silent (SNP) | VAF 46/472 reads (10%) | called by muse, mutect2
- DUSP5 | c.327C>T p.L109= | Silent (SNP) | VAF 39/317 reads (12%) | called by muse, mutect2, varscan2
- DUSP9 | c.420C>T p.T140= | Silent (SNP) | VAF 50/610 reads (8%) | called by muse, mutect2
- ENGASE | c.1393C>T p.L465= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV56138004; called by muse, mutect2
- FAHD2A | c.777G>C p.L259= | Silent (SNP) | VAF 29/247 reads (12%) | called by muse, mutect2, varscan2
- FKBP10 | c.474G>A p.V158= | Silent (SNP) | VAF 35/442 reads (8%) | called by muse, mutect2
- FZD5 | c.144G>A p.L48= | Silent (SNP) | VAF 28/486 reads (6%) | called by muse, mutect2
- GDF10 | c.1359C>T p.V453= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as rs376782261; called by muse, mutect2
- GOLGA3 | c.2973G>A p.E991= | Silent (SNP) | VAF 25/359 reads (7%) | called by muse, mutect2
- GPATCH2 | c.204G>A p.R68= | Silent (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- HELZ2 | c.3480C>T p.R1160= (on ENST00000467148 / NM_001037335.2; = p.R591= on NM_033405.3) | Silent (SNP) | VAF 39/374 reads (10%) | called by muse, mutect2, varscan2
- HSDL2 | c.669C>T p.I223= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, varscan2
- INTS2 | c.3079C>T p.L1027= | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- KCNC4 | c.186C>T p.L62= | Silent (SNP) | VAF 31/225 reads (14%) | called by muse, mutect2, varscan2
- KCNJ10 | c.795G>A p.L265= | Silent (SNP) | VAF 36/599 reads (6%) | catalogued as rs935548778; called by muse, mutect2
- KLK12 | c.240C>G p.L80= | Silent (SNP) | VAF 22/706 reads (3%) | called by muse, mutect2
- MARCHF2 | c.280C>T p.L94= | Silent (SNP) | VAF 52/574 reads (9%) | called by muse, mutect2
- MEF2A | c.1125C>T p.L375= (on ENST00000557942 / NM_001319206.2; = p.L369= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs1006214888, COSV57536746; called by muse, mutect2
- MKRN3 | c.300C>T p.I100= | Silent (SNP) | VAF 42/345 reads (12%) | catalogued as rs1337381352, COSV100090566; called by muse, mutect2, varscan2
- NCOA2 | c.2475G>A p.T825= | Silent (SNP) | VAF 40/614 reads (7%) | catalogued as rs202019914, COSV51219053, COSV99144797; called by muse, mutect2
- NHLH2 | c.279C>T p.F93= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as COSV57201924; called by muse, mutect2
- NOP14 | c.2421C>T p.I807= | Silent (SNP) | VAF 12/350 reads (3%) | catalogued as rs1271684489; called by muse, mutect2
- OLFM1 | c.282G>A p.L94= (on ENST00000371793 / NM_001282611.2; = p.L76= on NM_006334.4) | Silent (SNP) | VAF 38/249 reads (15%) | called by muse, varscan2
- OPA1 | c.2553G>A p.E851= (on ENST00000361510 / NM_130837.3; = p.E796= on NM_015560.3) | Silent (SNP) | VAF 15/218 reads (7%) | called by muse, mutect2
- PLXNA2 | c.4506G>A p.L1502= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs746884893; called by mutect2, varscan2
- RUSC1 | c.1608C>T p.H536= (on ENST00000368352 / NM_001105203.2; = p.H67= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/330 reads (8%) | catalogued as COSV52740727; called by muse, mutect2
- SEC24D | c.1380C>A p.L460= | Silent (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2
- SEH1L | c.21C>A p.I7= | Silent (SNP) | VAF 18/297 reads (6%) | catalogued as COSV50818306; called by muse, mutect2
- SETDB1 | c.594G>C p.L198= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- SIRT3 | c.249G>A p.P83= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- SLAMF9 | c.702C>T p.F234= | Silent (SNP) | VAF 13/262 reads (5%) | catalogued as COSV63637368; called by muse, mutect2
- SNX6 | c.1191G>A p.L397= (on ENST00000652385; = p.L269= on NM_021249.5) | Silent (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2
- TDRD1 | c.2226C>G p.L742= | Silent (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- TNNC2 | c.264G>A p.A88= | Silent (SNP) | VAF 48/420 reads (11%) | catalogued as rs867044515; called by muse, mutect2, varscan2
- TPP2 | c.2637G>A p.L879= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- VPS13C | c.3285C>G p.V1095= (on ENST00000644861 / NM_020821.3; = p.V1052= on NM_017684.5) | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV51192523; called by muse, mutect2, varscan2
- ZMIZ1 | c.429T>C p.D143= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, varscan2
- ZNF324B | c.567C>T p.P189= | Silent (SNP) | VAF 46/493 reads (9%) | called by muse, mutect2
- ZNF460 | c.831G>A p.E277= | Silent (SNP) | VAF 28/239 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.1134C>T p.C378= | Silent (SNP) | VAF 19/202 reads (9%) | catalogued as rs755287534, COSV62820506; called by muse, mutect2
- ADAMTS20 | c.4284+1796G>C | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- AP000769.5 | chr11:65499509 G>T | 5'Flank (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2
- AP000769.5 | chr11:65499648 G>A | 5'Flank (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
- AP000769.5 | chr11:65500204 G>C | 5'Flank (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2
- CASKIN2 | c.487-30G>C | Intron (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- CD84 | c.778+27C>A | Intron (SNP) | VAF 32/512 reads (6%) | called by muse, mutect2
- CLUHP11 | n.216C>T | RNA (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- COX6A1P2 | n.137C>T | RNA (SNP) | VAF 46/750 reads (6%) | catalogued as rs1173602724; called by muse, mutect2
- EFR3A | c.-61C>A | 5'UTR (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2
- GFPT1 | c.-34C>G | 5'UTR (SNP) | VAF 50/504 reads (10%) | called by muse, mutect2, varscan2
- GRIP2 | c.857+17G>A | Intron (SNP) | VAF 30/498 reads (6%) | called by muse, mutect2
- GVINP1 | n.4921C>G | RNA (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- HSPA7 | n.996G>C | RNA (SNP) | VAF 83/1034 reads (8%) | catalogued as rs771040359; called by muse, mutect2
- IGF1R | c.2486-40G>A | Intron (SNP) | VAF 19/155 reads (12%) | catalogued as rs950703709; called by muse, mutect2, varscan2
- IGFN1 | c.1241+2662G>A | Intron (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- ILK | c.448+34C>T | Intron (SNP) | VAF 70/774 reads (9%) | catalogued as rs1457715366; called by muse, mutect2
- JAKMIP1 | chr4:6049859 G>C | 3'Flank (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- MIA2 | c.249+166G>C | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- MYC | c.-33C>T | 5'UTR (SNP) | VAF 46/664 reads (7%) | called by muse, mutect2
- MYO18A | c.1000-6178C>T | Intron (SNP) | VAF 22/376 reads (6%) | called by muse, mutect2
- PLTP | c.*50C>T | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs1431684147; called by muse, mutect2
- PRCD | chr17:76544133 C>T | 3'Flank (SNP) | VAF 85/790 reads (11%) | called by muse, mutect2, varscan2
- PRCD | chr17:76544134 C>T | 3'Flank (SNP) | VAF 83/789 reads (11%) | catalogued as rs1205032795; called by muse, mutect2, varscan2
- PTCD1 | c.*2356G>C | 3'UTR (SNP) | VAF 21/258 reads (8%) | called by muse, mutect2
- REXO1L1P | n.8C>G | RNA (SNP) | VAF 41/813 reads (5%) | catalogued as rs1205386069; called by muse, mutect2
- SHH | c.*2730G>A | 3'UTR (SNP) | VAF 50/562 reads (9%) | catalogued as rs535026654; called by muse, mutect2
- SLAMF8 | chr1:159841135 G>A | 3'Flank (SNP) | VAF 30/359 reads (8%) | called by muse, mutect2
- SNORD115-19 | n.76G>A | RNA (SNP) | VAF 22/203 reads (11%) | called by muse, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 35/367 reads (10%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2
- TBX2 | chr17:61412215 G>A | 3'Flank (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- TBXAS1 | c.1134+37C>T | Intron (SNP) | VAF 18/180 reads (10%) | catalogued as rs1406795803, COSV54941946; called by muse, mutect2
- UBE2W | c.-1C>T | 5'UTR (SNP) | VAF 21/353 reads (6%) | catalogued as rs1188561473; called by muse, mutect2
